Somatic mutation profile of tumor specimen TARGET-40-NAAGKG-01A (aliquot TARGET-40-NAAGKG-01A-01D) from TARGET case TARGET-40-NAAGKG, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 18.3 years (6,683 days).
Specimen TARGET-40-NAAGKG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7673ab9-04b3-4dbd-b37b-5f6ae23f5310.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAGKG-10B (Blood Derived Normal), aliquot TARGET-40-NAAGKG-10B-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2c9173c-e0d2-4f34-b287-594754c0997b

The open-access MAF lists 47 somatic variants for this specimen: 28 protein-altering or splice-affecting, 11 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 11, Intron 4, Nonsense Mutation 3, 5'Flank 2, Splice Site 2, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AF196969.1 | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 56/227 reads (25%) | catalogued as rs587783613, CM001136; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP7B | c.562C>T p.Q188* | Nonsense Mutation (SNP) | VAF 13/121 reads (11%) | catalogued as rs1412593296, CM076010, COSV54440288; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CTNNA3 | c.1894G>T p.E632* | Nonsense Mutation (SNP) | VAF 29/83 reads (35%) | catalogued as COSV65560206; called by muse, mutect2, varscan2
- GPBP1 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.942); catalogued as rs767453704; called by muse, mutect2, varscan2
- HOXA7 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs764552031; called by muse, mutect2, varscan2
- KDM4D | c.1363C>T p.R455C | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.076); catalogued as rs782590036, COSV58634529; called by muse, mutect2, varscan2
- KDM8 | c.616G>C p.V206L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as rs758199328; called by muse, mutect2, varscan2
- MYO18B | c.5565G>T p.K1855N | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1222520064; called by muse, mutect2, varscan2
- PCLO | c.5114C>A p.T1705K | Missense Mutation (SNP) | VAF 77/179 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1000697594; called by muse, mutect2, varscan2
- PLXNA3 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 61/112 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.505); catalogued as rs782215325, COSV100859888; called by muse, mutect2, varscan2
- PPP1R3A | c.2152G>C p.D718H | Missense Mutation (SNP) | VAF 95/606 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV52875833; called by muse, mutect2, varscan2
- TNS1 | c.4189C>T p.R1397W | Missense Mutation (SNP) | VAF 58/109 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368264531; called by muse, mutect2, varscan2
- UGT2B10 | c.1412G>C p.G471A | Missense Mutation (SNP) | VAF 17/243 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55323974; called by muse, mutect2
- CCDC168 | c.7981C>T p.P2661S | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- CLECL1 | c.230G>A p.C77Y | Missense Mutation (SNP) | VAF 11/220 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CMIP | c.986C>T p.A329V (on ENST00000537098 / NM_198390.2; = p.A235V on NM_030629.3) | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- COL1A1 | c.2667+1_2667+2del p.X889_splice | Splice Site (DEL) | VAF 102/309 reads (33%) | called by mutect2, pindel, varscan2
- ENDOU | c.589C>G p.P197A (on ENST00000422538 / NM_001172439.2; = p.P156A on NM_006025.4) | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FAT1 | c.5684G>C p.G1895A | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IL1RAPL2 | c.1332C>G p.F444L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MTPAP | c.625C>T p.L209F | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- NFATC1 | c.2783-1G>A p.X928_splice (on ENST00000427363 / NM_001278669.2; = p.X826_splice on NM_006162.5) | Splice Site (SNP) | VAF 20/51 reads (39%) | called by muse, mutect2, varscan2
- NRXN3 | c.405G>T p.Q135H | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- PDE7A | c.766C>G p.H256D (on ENST00000401827 / NM_001242318.3; = p.H230D on NM_002603.4) | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RPL26 | c.324G>C p.R108S | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.548); called by muse, mutect2
- SLC7A1 | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- TRBV23-1 | c.214C>A p.Q72K | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.77); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- UGT2B11 | c.641T>A p.M214K | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); called by muse, mutect2
- CASR | c.2691C>G p.T897= (on ENST00000490131; = p.T974= on NM_000388.4) | Silent (SNP) | VAF 32/135 reads (24%) | catalogued as COSV56137770; called by muse, mutect2, varscan2
- CYLC2 | c.177T>A p.V59= | Silent (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2, varscan2
- EIF2AK1 | c.588A>G p.K196= | Silent (SNP) | VAF 17/71 reads (24%) | called by muse, mutect2, varscan2
- KLHDC7B | c.1236C>T p.G412= (on ENST00000395676; = p.G1053= on NM_138433.5) | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs769685749, COSV67464813; called by muse, mutect2, varscan2
- PALLD | c.1353C>T p.A451= | Silent (SNP) | VAF 42/194 reads (22%) | catalogued as rs763960529; called by muse, mutect2, varscan2
- PAPPA2 | c.3930T>C p.S1310= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as rs371375924; called by muse, mutect2, varscan2
- QSER1 | c.1128G>A p.L376= (on ENST00000399302; = p.L505= on NM_001076786.3) | Silent (SNP) | VAF 18/102 reads (18%) | called by muse, mutect2, varscan2
- SLC26A1 | c.1044G>A p.L348= | Silent (SNP) | VAF 55/79 reads (70%) | catalogued as rs1250937550; called by muse, mutect2, varscan2
- SLC26A4 | c.1411C>T p.L471= | Silent (SNP) | VAF 59/269 reads (22%) | catalogued as rs1224848656, COSV55917378; called by muse, mutect2, varscan2
- TBCEL | c.360A>C p.T120= | Silent (SNP) | VAF 32/133 reads (24%) | catalogued as COSV52459823; called by muse, mutect2, varscan2
- TEX15 | c.3507A>G p.G1169= (on ENST00000256246; = p.G1552= on NM_001350162.2) | Silent (SNP) | VAF 16/87 reads (18%) | called by muse, mutect2, varscan2
- DHX15 | c.-14C>A | 5'UTR (SNP) | VAF 419/722 reads (58%) | called by muse, varscan2
- EFHC1 | c.723+73G>C | Intron (SNP) | VAF 65/364 reads (18%) | called by muse, mutect2, varscan2
- ELFN1 | c.-456+5638G>A | Intron (SNP) | VAF 22/144 reads (15%) | catalogued as rs551141573; called by muse, mutect2, varscan2
- MAP2K3 | c.50-2662G>T | Intron (SNP) | VAF 24/431 reads (6%) | called by muse, mutect2
- MIR6859-3 | chr15:101977380 G>T | 3'Flank (SNP) | VAF 26/259 reads (10%) | called by muse, mutect2, varscan2
- MIR6859-4 | chr16:17685 G>A | 5'Flank (SNP) | VAF 38/219 reads (17%) | catalogued as rs551367473; called by muse, varscan2
- TTC22 | c.1020+396C>T | Intron (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- ZNF578 | chr19:52451424 C>T | 5'Flank (SNP) | VAF 10/53 reads (19%) | called by muse, mutect2, varscan2
